Somatic mutation profile of tumor specimen 0D97Y3 from CCDI case PBBIBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, benign; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.3 years (5,968 days).
Specimen 0D97Y3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b02eb6f-8abe-4694-9f6c-93e02ed34724.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D97Y5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8154ccc2-078f-48fd-866b-59f0dadf7b7f

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Del 1, RNA 1, Intron 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EMILIN1 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.301); called by muse, mutect2
- FOXRED1 | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- OXER1 | c.796del p.A266Rfs*8 | Frame Shift Del (DEL) | VAF 3/37 reads (8%) | called by mutect2, varscan2
- AC106895.1 | n.438G>T | RNA (SNP) | VAF 3/36 reads (8%) | called by mutect2, varscan2
- ELOF1 | c.*16G>A | 3'UTR (SNP) | VAF 6/70 reads (9%) | catalogued as rs1370835715; called by muse, mutect2
- PPARA | c.-30del | 5'UTR (DEL) | VAF 2/20 reads (10%) | catalogued as COSV99415345; called by mutect2, varscan2
- SPDYE3 | c.1590+40T>A | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
